Somatic mutation profile of tumor specimen MMRF_2226_1_BM_CD138pos (aliquot MMRF_2226_1_BM_CD138pos_T3_KHS5U_K14025) from MMRF case MMRF_2226, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,616 days).
Specimen MMRF_2226_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c94c188c-966b-4828-8994-b84f2d1f8877.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2226_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2226_1_PB_Whole_C1_KHS5U_K14024; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aedd62e7-be94-4a20-aba0-425929a535ea

The open-access MAF lists 110 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 51 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, 3'UTR 31, Intron 13, Silent 12, 5'UTR 3, Nonsense Mutation 2, In Frame Del 2, 3'Flank 2, RNA 1, 5'Flank 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 41/106 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- IGHV2-70 | c.276G>C p.K92N | Missense Mutation (SNP) | VAF 26/37 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs371562118; called by muse, varscan2
- IGHV2-70 | c.179A>C p.Q60P | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs539008662; called by muse, varscan2
- IGHV2-70 | c.139T>C p.S47P | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs544365977; called by muse, varscan2
- IGHV2-70 | c.59A>T p.Q20L | Missense Mutation (SNP) | VAF 28/71 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as rs1567837962; called by muse, varscan2
- IGKV4-1 | c.229G>A p.A77T | Missense Mutation (SNP) | VAF 38/38 reads (100%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.599); catalogued as rs758803569; called by muse, varscan2
- IGLL5 | c.185G>A p.S62N | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as rs751510190, COSV73251127; called by muse, mutect2, varscan2
- IGLV3-1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 40/83 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs144850905; called by muse, varscan2
- IGLV3-1 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 46/94 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs555443658; called by muse, varscan2
- IGLV3-1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 47/97 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.027); catalogued as rs371113616; called by muse, varscan2
- IGLV3-1 | c.302A>C p.E101A | Missense Mutation (SNP) | VAF 48/110 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs532827838; called by muse, mutect2, varscan2
- IGLV4-3 | c.164A>C p.Y55S | Missense Mutation (SNP) | VAF 70/143 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs778196121; called by muse, mutect2, varscan2
- KL | c.1255G>T p.V419F | Missense Mutation (SNP) | VAF 67/87 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs752616565; called by muse, mutect2, varscan2
- KLHL6 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 52/87 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV100384822; called by muse, mutect2, varscan2
- KRT2 | c.365G>A p.R122H | Missense Mutation (SNP) | VAF 51/102 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.374); catalogued as rs774545316, COSV99046541; called by muse, mutect2, varscan2
- OR6B1 | c.199T>A p.S67T | Missense Mutation (SNP) | VAF 55/245 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV68770706; called by muse, mutect2, varscan2
- PEX1 | c.671G>T p.G224V | Missense Mutation (SNP) | VAF 37/143 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as rs749874311; called by muse, mutect2, varscan2
- RPA2 | c.399A>C p.R133S | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100536141; called by muse, mutect2, varscan2
- SLC16A1 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480274755; called by muse, mutect2, varscan2
- TBC1D4 | c.70G>A p.A24T | Missense Mutation (SNP) | VAF 44/46 reads (96%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.01); catalogued as rs772651134; called by muse, mutect2, varscan2
- UNC5C | c.2003C>A p.A668D | Missense Mutation (SNP) | VAF 28/64 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV71658459, COSV71662217; called by muse, mutect2, varscan2
- ABCC11 | c.362C>T p.S121L | Missense Mutation (SNP) | VAF 36/37 reads (97%) | SIFT deleterious (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- BBOF1 | c.82G>A p.V28M | Missense Mutation (SNP) | VAF 28/59 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- BTG1 | c.83_107del p.T28Sfs*44 | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- CNOT10 | c.971A>T p.D324V | Missense Mutation (SNP) | VAF 60/203 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CNTN4 | c.1133A>G p.D378G | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSDE1 | c.834C>A p.N278K (on ENST00000358528 / NM_001007553.3; = p.N247K on NM_007158.6) | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- FOLH1 | c.1989G>A p.M663I | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- GALNT13 | c.832A>T p.K278* | Nonsense Mutation (SNP) | VAF 20/47 reads (43%) | called by muse, mutect2, varscan2
- HACE1 | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 74/192 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.921); called by muse, varscan2
- INTU | c.1613T>C p.I538T | Missense Mutation (SNP) | VAF 56/123 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- LRRC53 | c.1675A>C p.K559Q | Missense Mutation (SNP) | VAF 38/76 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.413); called by muse, mutect2, varscan2
- MAB21L4 | c.1043T>G p.L348R (on ENST00000388934 / NM_001085437.3; = p.L180R on NM_024861.4) | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MAST1 | c.3728C>A p.P1243H | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MOCS1 | c.1398_1406del p.W467_S469del | In Frame Del (DEL) | VAF 38/98 reads (39%) | called by mutect2, pindel, varscan2
- MORC2 | c.123-2A>G p.X41_splice | Splice Site (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- MSLNL | c.1955G>T p.C652F | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PRKCH | c.593A>G p.K198R | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- RDH8 | c.794T>A p.V265D (on ENST00000651512; = p.V245D on NM_015725.4) | Missense Mutation (SNP) | VAF 102/435 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SH2D4B | c.1257C>A p.C419* (on ENST00000646907; = p.R345= on NM_207372.2) | Nonsense Mutation (SNP) | VAF 166/427 reads (39%) | called by muse, mutect2, varscan2
- SNAP25 | c.538A>G p.R180G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.555); called by muse, mutect2, varscan2
- SOGA3 | c.2312G>A p.R771H | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- TOPORS | c.2153C>T p.S718L | Missense Mutation (SNP) | VAF 56/263 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.052); called by muse, mutect2, varscan2
- TRBV9 | c.35G>A p.C12Y | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2, varscan2
- TTN | c.97543G>T p.V32515L (on ENST00000591111; = p.V25091L on NM_003319.4) | Missense Mutation (SNP) | VAF 94/204 reads (46%) | PolyPhen benign (0.013); called by muse, varscan2
- UNC119 | c.178A>C p.I60L | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF222 | c.816_825delinsA p.N273_H275del | In Frame Del (DEL) | VAF 53/232 reads (23%) | called by pindel, varscan2*
- BTG1 | c.109C>T p.L37= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs369374957, COSV55458204, COSV55458724; called by mutect2, varscan2
- CHL1 | c.1893C>T p.T631= (on ENST00000397491 / NM_001253387.1; = p.T647= on NM_006614.4) | Silent (SNP) | VAF 79/271 reads (29%) | catalogued as rs1276845517; called by muse, mutect2, varscan2
- DSCAML1 | c.5286C>G p.V1762= (on ENST00000321322; = p.V1702= on NM_020693.4) | Silent (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- GLP2R | c.495C>T p.F165= | Silent (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- LAMB4 | c.4479C>T p.N1493= | Silent (SNP) | VAF 53/211 reads (25%) | catalogued as rs762529031, COSV52723268; called by muse, mutect2, varscan2
- MPDZ | c.6108G>A p.Q2036= (on ENST00000319217 / NM_001330637.2; = p.Q2007= on NM_003829.5) | Silent (SNP) | VAF 75/166 reads (45%) | called by muse, mutect2, varscan2
- NEB | c.1686G>A p.K562= | Silent (SNP) | VAF 27/54 reads (50%) | called by muse, mutect2, varscan2
- PRMT2 | c.681G>A p.L227= | Silent (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- SGSM1 | c.156C>T p.C52= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs373776159; called by muse, mutect2, varscan2
- SLC4A1 | c.2580C>T p.P860= | Silent (SNP) | VAF 21/77 reads (27%) | catalogued as rs879009881; called by muse, mutect2, varscan2
- SMARCC2 | c.33C>T p.N11= | Silent (SNP) | VAF 12/207 reads (6%) | called by muse, mutect2
- SND1 | c.2595G>A p.V865= | Silent (SNP) | VAF 38/174 reads (22%) | called by muse, mutect2, varscan2
- AC020688.1 | n.325C>T | RNA (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2
- ACSBG1 | c.*625T>A | 3'UTR (SNP) | VAF 45/125 reads (36%) | called by muse, mutect2, varscan2
- ALPG | c.*207G>T | 3'UTR (SNP) | VAF 20/66 reads (30%) | called by muse, mutect2, varscan2
- CA6 | c.*132G>A | 3'UTR (SNP) | VAF 76/151 reads (50%) | called by muse, mutect2, varscan2
- CCL22 | c.*1480C>T | 3'UTR (SNP) | VAF 43/50 reads (86%) | catalogued as rs1395863262; called by muse, mutect2, varscan2
- CD276 | c.1582+626G>T | Intron (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2
- CFAP298-TCP10L | c.-556G>T | 5'UTR (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2, varscan2
- CNTNAP2 | c.1898-237C>A | Intron (SNP) | VAF 11/73 reads (15%) | called by muse, mutect2, varscan2
- CRHR2 | c.*509A>C | 3'UTR (SNP) | VAF 18/106 reads (17%) | called by mutect2, varscan2
- CSNK2A1 | c.*827G>A | 3'UTR (SNP) | VAF 23/62 reads (37%) | called by muse, mutect2, varscan2
- DAAM1 | c.2664-12T>C | Intron (SNP) | VAF 12/27 reads (44%) | called by muse, mutect2
- DNAL1 | c.*1566C>T | 3'UTR (SNP) | VAF 5/11 reads (45%) | catalogued as rs1392247908; called by muse, mutect2, varscan2
- EPN3 | c.*285G>A | 3'UTR (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- ETV5 | c.*319C>T | 3'UTR (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- FGF12 | c.*184G>A | 3'UTR (SNP) | VAF 48/131 reads (37%) | called by muse, mutect2, varscan2
- FGF7 | c.286+566A>G | Intron (SNP) | VAF 47/69 reads (68%) | called by muse, mutect2, varscan2
- FOLH1 | c.826+46A>G | Intron (SNP) | VAF 13/28 reads (46%) | called by muse, mutect2
- GABRA4 | c.*7115A>C | 3'UTR (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- GABRB2 | c.*4105A>T | 3'UTR (SNP) | VAF 5/69 reads (7%) | called by muse, mutect2
- GNA14 | c.*325G>A | 3'UTR (SNP) | VAF 42/138 reads (30%) | catalogued as rs974654973; called by muse, mutect2, varscan2
- GVQW3 | c.644+535G>A | Intron (SNP) | VAF 52/106 reads (49%) | catalogued as rs563677662; called by muse, mutect2, varscan2
- HNRNPUL2 | c.*1966C>T | 3'UTR (SNP) | VAF 37/80 reads (46%) | catalogued as rs1206622506; called by muse, mutect2, varscan2
- IFNA6 | c.*119C>T | 3'UTR (SNP) | VAF 75/372 reads (20%) | catalogued as rs532080334; called by muse, mutect2, varscan2
- KPNA4 | c.-179G>T | 5'UTR (SNP) | VAF 7/24 reads (29%) | called by muse, mutect2, varscan2
- LRWD1 | c.1443-773C>A | Intron (SNP) | VAF 57/211 reads (27%) | called by muse, mutect2, varscan2
- MAU2 | c.*835T>C | 3'UTR (SNP) | VAF 44/261 reads (17%) | called by muse, mutect2, varscan2
- MAZ | c.*841_*845del | 3'UTR (DEL) | VAF 10/53 reads (19%) | called by mutect2, pindel, varscan2
- MEIS2 | c.*1178G>A | 3'UTR (SNP) | VAF 28/110 reads (25%) | called by muse, mutect2, varscan2
- MINPP1 | c.*423C>T | 3'UTR (SNP) | VAF 20/41 reads (49%) | called by muse, mutect2, varscan2
- MYO9A | c.*4023T>C | 3'UTR (SNP) | VAF 9/107 reads (8%) | catalogued as rs917296626; called by muse, mutect2
- OR4Q2 | chr14:20003175 G>C | 3'Flank (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- PDGFRB | c.*891G>A | 3'UTR (SNP) | VAF 26/94 reads (28%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1636+570T>G | Intron (SNP) | VAF 38/100 reads (38%) | called by muse, mutect2, varscan2
- PHF20L1 | c.1637-544T>C | Intron (SNP) | VAF 30/61 reads (49%) | called by muse, mutect2, varscan2
- PIK3C2A | c.*164C>T | 3'UTR (SNP) | VAF 9/24 reads (38%) | called by muse, mutect2, varscan2
- PPP2R5E | c.*2284T>A | 3'UTR (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- RAB27A | c.*1573del | 3'UTR (DEL) | VAF 12/57 reads (21%) | called by mutect2, pindel, varscan2
- RBFOX2 | c.*1002T>C | 3'UTR (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- RNU6-955P | chr17:4616809 T>C | 3'Flank (SNP) | VAF 21/76 reads (28%) | called by muse, mutect2, varscan2
- ROBO1 | c.3374-420G>C | Intron (SNP) | VAF 66/101 reads (65%) | called by muse, mutect2, varscan2
- SAYSD1 | c.*317C>A | 3'UTR (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- SEMA3C | c.*2348A>C | 3'UTR (SNP) | VAF 12/56 reads (21%) | called by muse, mutect2
- SH3BGRL2 | c.*476G>A | 3'UTR (SNP) | VAF 21/47 reads (45%) | called by muse, mutect2, varscan2
- SLC25A37 | c.*1402A>G | 3'UTR (SNP) | VAF 64/131 reads (49%) | called by muse, mutect2, varscan2
- SLC3A2 | chr11:62853630 C>T | 5'Flank (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- SLC6A19 | c.*2537A>T | 3'UTR (SNP) | VAF 68/268 reads (25%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.-28T>C | 5'UTR (SNP) | VAF 77/196 reads (39%) | called by muse, mutect2, varscan2
- TGM3 | c.*489C>T | 3'UTR (SNP) | VAF 57/126 reads (45%) | catalogued as rs971265128; called by muse, mutect2, varscan2
- UBE3A | c.29+1405C>G | Intron (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- VPS13C | c.10863+626C>T | Intron (SNP) | VAF 14/62 reads (23%) | called by mutect2, varscan2
- ZNF638 | c.3136-142C>T | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
